Gene-level copy-number profile of tumor specimen C3L-00977-02 from CPTAC case C3L-00977, project CPTAC-3 (Other and ill-defined sites in lip, oral cavity and pharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 56.5 years (20,653 days).
Specimen C3L-00977-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oral Cavity; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74741da1-c3e8-4216-ba07-41074ace6c50.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00977-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,707 have no estimate.
https://portal.gdc.cancer.gov/files/c3fffd66-e0da-4748-a804-ff9bad656c16

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 532; copy number 1: 7,550; copy number 2: 49,419; copy number 3: 1,336; copy number 4: 3; copy number 5: 2; copy number 6: 29; copy number 9: 7; copy number 11: 33; copy number 12: 5.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:75,415,070–75,422,143, 1 gene (within-gene range 0–1): ALG1L6P.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–2): AL359922.1.
- chr9:21,892,188–22,214,672, 11 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 76 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 9: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr8:38,386,207–38,409,527, 1 gene, copy number 5: LETM2.
- chr8:38,408,048–38,408,742, 1 gene, copy number 5: AC087623.3.
- chr11:69,048,932–69,819,416, 20 genes, copy number 11: TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:70,078,302–70,398,488, 13 genes, copy number 11 (within-gene range 1–11): ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:71,382,601–71,524,107, 5 genes, copy number 12 (within-gene range 1–12): ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754.
- chr16:71,729,000–72,822,781, 29 genes, copy number 6 (within-gene range 1–6): AP1G1, SNORD71, AC010653.3, AC010653.1, ATXN1L, IST1, AC010653.2, ZNF821, AC009127.1, PKD1L3, RPL39P31, AC009127.2, ATP5F1AP3, DHODH, TXNL4B, HP, HPR, AC009087.1, DHX38, PMFBP1, AC009075.1, LINC01572, AC009075.2, U6, AC004158.1, AC004943.2, RNU7-90P, KRT18P18, AC004943.3.

Autosomal genes at a single copy (total copy number 1): 5,215. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
